Somatic mutation profile of tumor specimen TCGA-85-8070-01A (aliquot TCGA-85-8070-01A-11D-2244-08) from TCGA case TCGA-85-8070, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.7 years (26,183 days).
Specimen TCGA-85-8070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d0c6b6e-e463-453b-a7f1-c80115f0a4f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8070-10A (Blood Derived Normal), aliquot TCGA-85-8070-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/100e31ac-ba11-4988-8d5e-553e350bba8d

The open-access MAF lists 247 somatic variants for this specimen: 203 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 41, Nonsense Mutation 8, Splice Site 7, Frame Shift Del 7, Frame Shift Ins 4, RNA 2, Translation Start Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 47/52 reads (90%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4096G>C p.A1366P | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100711236; called by muse, mutect2, varscan2
- ADCK2 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 95/157 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301704; called by muse, mutect2, varscan2
- ADCK5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs782782811, COSV100450557; called by muse, mutect2, varscan2
- ADGRB3 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV65409403, COSV65411202; called by muse, mutect2, varscan2
- ADGRB3 | c.1207T>C p.W403R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1325616615, COSV101001004; called by muse, mutect2, varscan2
- AFAP1 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV100631758; called by muse, mutect2, varscan2
- AGAP1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.122); catalogued as COSV100365805; called by muse, mutect2, varscan2
- AGMO | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV100694231, COSV100694335; called by muse, mutect2, varscan2
- AHDC1 | c.1973T>G p.F658C | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs1357539478, COSV99899475; called by muse, mutect2, varscan2
- AHR | c.2317C>G p.Q773E | Missense Mutation (SNP) | VAF 86/150 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as rs757186338, COSV99619856; called by muse, mutect2, varscan2
- ALMS1 | c.9370G>T p.D3124Y | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042886; called by muse, mutect2, varscan2
- ANKS1B | c.2309C>A p.S770Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100246388; called by muse, mutect2, varscan2
- AOX1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV101022079; called by muse, mutect2, varscan2
- AP1S3 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100525284; called by muse, mutect2, varscan2
- ARVCF | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs886116986, COSV99599362; called by muse, mutect2
- ASB15 | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99306729; called by muse, mutect2, varscan2
- ATP6V0D2 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53413636, COSV53416476; called by muse, mutect2, varscan2
- BPIFB1 | c.1255-1G>T p.X419_splice | Splice Site (SNP) | VAF 100/205 reads (49%) | catalogued as COSV99487468; called by muse, mutect2, varscan2
- BRCA2 | c.6303T>G p.N2101K | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV101204410; called by muse, mutect2, varscan2
- C12orf50 | c.800G>T p.R267I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100072315, COSV53893440; called by muse, mutect2, varscan2
- C2orf80 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100378474; called by muse, mutect2, varscan2
- CADPS2 | c.1576A>G p.R526G | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as COSV100463771; called by muse, mutect2, varscan2
- CALCR | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV100810629; called by muse, mutect2, varscan2
- CASP8AP2 | c.4444T>G p.L1482V | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99387194; called by muse, mutect2, varscan2
- CDC25B | c.851C>T p.A284V (on ENST00000245960 / NM_021873.3; = p.A270V on NM_004358.4) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99848038; called by muse, mutect2, varscan2
- CDC42BPA | c.4145G>C p.R1382T (on ENST00000334218 / NM_001366019.2; = p.R1369T on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV100505847; called by muse, mutect2, varscan2
- CDH18 | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99936075; called by muse, mutect2, varscan2
- CDK12 | c.1907T>A p.L636* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV101420488; called by muse, mutect2, varscan2
- CEP135 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954615; called by muse, mutect2, varscan2
- CETN1 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as COSV100511358, COSV59122299; called by muse, mutect2, varscan2
- CFAP44 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99869900; called by muse, mutect2
- CGGBP1 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV58851376; called by muse, mutect2, varscan2
- CNTNAP2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs886062050, COSV62240443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101443738, COSV70479012; called by muse, mutect2, varscan2
- CNTROB | c.2273A>G p.H758R | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.135); catalogued as COSV100972712; called by muse, mutect2, varscan2
- COL11A1 | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774767622, COSV100617164; called by muse, mutect2, varscan2
- COL15A1 | c.261C>A p.F87L | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100897837; called by muse, mutect2, varscan2
- CREBBP | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99270659; called by muse, mutect2, varscan2
- CRYZ | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100558640; called by muse, mutect2, varscan2
- CSE1L | c.1978A>T p.I660F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV99522085; called by muse, varscan2
- DCAF4L2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV60476348; called by muse, mutect2, varscan2
- DGCR8 | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100708044, COSV61225549; called by muse, mutect2, varscan2
- DGKI | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55961426, COSV99935591; called by muse, mutect2, varscan2
- DNAH3 | c.10219T>A p.Y3407N | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as COSV99768485; called by muse, mutect2, varscan2
- DNAH5 | c.11217G>C p.L3739F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451212; called by muse, mutect2, varscan2
- DYRK1A | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT tolerated (0.34); PolyPhen benign (0.347); catalogued as COSV100118011; called by muse, mutect2, varscan2
- EBAG9 | c.292A>T p.M98L | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV100520832; called by muse, mutect2, varscan2
- EDNRB | c.943A>T p.I315F (on ENST00000377211 / NM_001201397.1; = p.I225F on NM_000115.5) | Missense Mutation (SNP) | VAF 81/100 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100526797; called by muse, mutect2, varscan2
- EGFLAM | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100380444; called by muse, mutect2, varscan2
- EIF4G2 | c.1711A>G p.M571V | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs1182180532, COSV101150943; called by muse, mutect2
- ENPP1 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62929723; called by muse, mutect2, varscan2
- EPHA1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 107/154 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1287321074, COSV99314239; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1174C>G p.R392G | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99212515; called by muse, mutect2
- EVI2A | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907633; called by muse, mutect2, varscan2
- FIGN | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100292548; called by muse, mutect2, varscan2
- FLG | c.10505C>A p.S3502* | Nonsense Mutation (SNP) | VAF 12/360 reads (3%) | catalogued as COSV100911700; called by muse, mutect2
- FLNC | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 381/578 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100368328; called by muse, mutect2, varscan2
- FNBP4 | c.2861A>C p.Q954P | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99771790; called by muse, mutect2, varscan2
- FOXP2 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100646961; called by muse, mutect2, varscan2
- FUT6 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs548742760, COSV99744722; called by muse, mutect2, varscan2
- G6PC2 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99960811; called by muse, mutect2, varscan2
- GABRA5 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV100165395; called by muse, mutect2, varscan2
- GABRG1 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99778177, COSV99778315; called by muse, mutect2, varscan2
- GALNTL6 | c.1051T>A p.C351S | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101560331; called by muse, mutect2, varscan2
- GINS4 | c.546A>G p.I182M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52530849; called by muse, mutect2, varscan2
- GLDN | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764239923, COSV100117380; called by muse, mutect2, varscan2
- GOLGB1 | c.3781C>A p.P1261T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as COSV100511138; called by muse, mutect2, varscan2
- H2BC13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/33 reads (79%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.885); catalogued as rs368046141; called by muse, mutect2, varscan2
- HDAC9 | c.1949A>T p.N650I | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV101286841; called by muse, mutect2, varscan2
- HELB | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1321293311, COSV99922000; called by muse, mutect2, varscan2
- HEPH | c.1945C>A p.L649M (on ENST00000343002; = p.L382M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV100295099; called by mutect2, varscan2
- HIVEP2 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs372948812; called by muse, mutect2, varscan2
- HLTF | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100026919; called by muse, mutect2, varscan2
- HOOK1 | c.538-1G>A p.X180_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | catalogued as rs1014958319, COSV100969149; called by muse, mutect2, varscan2
- HOXA10 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs965322614, COSV99385528; called by muse, mutect2, varscan2
- HPCAL1 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100324078; called by muse, mutect2, varscan2
- HPCAL1 | c.491T>G p.L164R | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100324080; called by muse, mutect2, varscan2
- HTR2A | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1389863499, COSV101096736; called by muse, mutect2, varscan2
- HTR2C | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 74/79 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99349867; called by muse, mutect2, varscan2
- IFFO1 | c.1124A>G p.D375G (on ENST00000396840 / NM_001330324.2; = p.D378G on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV100351237; called by muse, mutect2, varscan2
- IGHV1-46 | c.198G>C p.W66C | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782265762; called by muse, mutect2, varscan2
- INO80 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs771768508, COSV100731902; called by muse, mutect2, varscan2
- IPO8 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV99805477, COSV99805518; called by muse, mutect2, varscan2
- ITGAX | c.2711A>G p.N904S | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99191837; called by muse, mutect2, varscan2
- ITIH5 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV99905055; called by muse, mutect2, varscan2
- JAKMIP2 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99507319; called by muse, mutect2, varscan2
- JMJD1C | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.304); catalogued as COSV100550662; called by muse, mutect2, varscan2
- JMJD1C | c.5204G>C p.R1735T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100550663, COSV59517914; called by muse, mutect2, varscan2
- KCNJ12 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1555562982, COSV100055310; called by muse, mutect2, varscan2
- KCNJ3 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291655705, COSV54546671, COSV99715041; called by muse, mutect2, varscan2
- KEAP1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50302633, COSV99407963; called by muse, mutect2, varscan2
- KIF3B | c.278T>A p.F93Y | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100996403; called by muse, mutect2, varscan2
- KIRREL2 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99384109; called by muse, mutect2, varscan2
- KLHL22 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.32); catalogued as rs759282661, COSV61019552; called by muse, mutect2, varscan2
- KLHL24 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV99664932; called by muse, mutect2, varscan2
- KNTC1 | c.6532G>T p.V2178F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs745779007, COSV100338478; called by muse, varscan2
- KRT15 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV99563142; called by muse, mutect2, varscan2
- LAMB1 | c.2333A>G p.Q778R | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99741158; called by muse, mutect2, varscan2
- LAMB3 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100620405; called by muse, mutect2, varscan2
- LCE2B | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV100909303, COSV100909319; called by muse, mutect2, varscan2
- LRP1B | c.1945G>T p.G649* | Nonsense Mutation (SNP) | VAF 77/125 reads (62%) | catalogued as COSV67271530; called by muse, mutect2, varscan2
- LRRC4 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 88/389 reads (23%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.042); catalogued as COSV99975085; called by muse, mutect2, varscan2
- LRRC8E | c.1386G>C p.L462F | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143018; called by muse, mutect2, varscan2
- LRRC8E | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100143019; called by muse, mutect2, varscan2
- LZTS1 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 15/20 reads (75%) | catalogued as COSV99743071; called by muse, mutect2, varscan2
- MAGEC2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 72/76 reads (95%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.13); catalogued as COSV99909715; called by muse, mutect2, varscan2
- MAN2C1 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747872496, COSV99145511; called by muse, mutect2, varscan2
- MARCO | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs866552930, COSV59052131; called by muse, mutect2, varscan2
- MED24 | c.2262G>C p.K754N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV100673265; called by muse, mutect2, varscan2
- MFSD14B | c.1014T>A p.F338L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV100942713; called by muse, mutect2
- MIDEAS | c.1364G>C p.R455P | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV54092422, COSV99679017; called by muse, mutect2, varscan2
- MMP16 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99689072; called by muse, mutect2, varscan2
- MORC2 | c.1297G>T p.A433S (on ENST00000397641 / NM_001303256.3; = p.A371S on NM_014941.3) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99310063; called by muse, mutect2, varscan2
- MORN1 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 39/46 reads (85%) | catalogued as COSV101047514, COSV66002996; called by muse, mutect2, varscan2
- MRC1 | c.3281T>C p.I1094T | Missense Mutation (SNP) | VAF 187/221 reads (85%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1208929007; called by muse, mutect2, varscan2
- MRPL30 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.73); catalogued as COSV100585452, COSV57667417; called by muse, mutect2, varscan2
- MS4A6E | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV100279180, COSV55726861; called by muse, mutect2, varscan2
- MSH6 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52283216, COSV99316332; called by muse, mutect2, varscan2
- MTMR11 | c.477G>T p.M159I (on ENST00000439741 / NM_001145862.2; = p.M87I on NM_181873.3) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV100809070; called by muse, mutect2
- MYH7 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100806262; called by muse, mutect2, varscan2
- NKX2-2 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV65819707, COSV65820393; called by muse, mutect2, varscan2
- NPS | c.185T>A p.L62* | Nonsense Mutation (SNP) | VAF 16/234 reads (7%) | catalogued as COSV101219399; called by muse, mutect2
- OR12D2 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV101011341; called by muse, mutect2, varscan2
- OR2J3 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs777512224, COSV101013639, COSV101013654; called by muse, mutect2, varscan2
- OR2M7 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100522404; called by muse, mutect2
- OR4A5 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100157166; called by muse, mutect2, varscan2
- OR51I2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244327018, COSV58299534; called by muse, mutect2, varscan2
- PACSIN3 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.864); catalogued as COSV100096423; called by muse, mutect2, varscan2
- PC | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); catalogued as rs749176333, COSV100547125, COSV100547206; called by muse, mutect2
- PCDH10 | c.3092C>A p.P1031Q | Missense Mutation (SNP) | VAF 69/86 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); catalogued as COSV99993909; called by muse, mutect2, varscan2
- PIM2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.229); catalogued as COSV99900328; called by muse, mutect2
- PITPNC1 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs753379672, COSV55447062; called by muse, mutect2, varscan2
- POTEE | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV100387964, COSV100388294; called by muse, mutect2, varscan2
- PPFIA2 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61039424; called by muse, mutect2, varscan2
- PXDNL | c.3848A>T p.N1283I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100684580; called by muse, mutect2, varscan2
- RAB3IL1 | c.745C>G p.R249G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV57117488; called by muse, mutect2
- RASGEF1C | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 162/176 reads (92%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV100746087; called by muse, mutect2, varscan2
- REG1B | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV59307274; called by muse, mutect2, varscan2
- RSRC1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV99906460; called by muse, mutect2, varscan2
- SCN4A | c.4664C>T p.P1555L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV101438551; called by muse, mutect2, varscan2
- SERPINE1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs143027028; called by muse, mutect2
- SLAMF6 | c.779A>G p.Q260R | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.294); catalogued as COSV100924902; called by muse, mutect2
- SLC18A2 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs201569242, COSV100041802; called by muse, mutect2, varscan2
- SLC22A9 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99655122; called by muse, mutect2, varscan2
- SLC24A3 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV100041723, COSV60111523; called by muse, mutect2, varscan2
- SLC26A4 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707198; called by muse, mutect2, varscan2
- SLC36A4 | c.62A>C p.D21A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100419412; called by muse, mutect2, varscan2
- SLC39A8 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100765809, COSV100765821; called by muse, mutect2, varscan2
- SLIT2 | c.3692+1G>T p.X1231_splice | Splice Site (SNP) | VAF 39/93 reads (42%) | catalogued as COSV99884981; called by muse, mutect2, varscan2
- SORL1 | c.6540G>T p.R2180S | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99494361; called by muse, mutect2, varscan2
- SOX6 | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV100322502, COSV100323324; called by muse, mutect2, varscan2
- SPATA31D1 | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100782860; called by mutect2, varscan2
- SPOUT1 | c.459-2A>G p.X153_splice | Splice Site (SNP) | VAF 37/81 reads (46%) | catalogued as COSV100778230; called by muse, mutect2, varscan2
- STAB2 | c.6371T>C p.I2124T | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1369990123, COSV101186100; called by muse, mutect2, varscan2
- STARD4 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99685349; called by muse, mutect2, varscan2
- SWT1 | c.1394G>T p.W465L | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100833372; called by muse, mutect2, varscan2
- SYNE1 | c.25962G>T p.K8654N (on ENST00000367255 / NM_182961.4; = p.K8606N on NM_033071.3) | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99569524; called by muse, mutect2, varscan2
- TDRD1 | c.1786A>T p.K596* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99314731; called by muse, mutect2, varscan2
- TECTA | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV99880334; called by muse, mutect2, varscan2
- TIRAP | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV101201641; called by muse, mutect2, varscan2
- TJP1 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100632856; called by muse, mutect2, varscan2
- TLL2 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100780341; called by muse, mutect2, varscan2
- TMEM267 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101231026; called by muse, mutect2, varscan2
- TMPRSS15 | c.2493C>G p.N831K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99518343; called by muse, mutect2, varscan2
- TMTC4 | c.115G>A p.D39N (on ENST00000376234 / NM_001350577.2; = p.D58N on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100168769; called by muse, mutect2, varscan2
- TOM1 | c.1476A>T p.L492F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101146843; called by muse, mutect2, varscan2
- TPTE | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as rs753249051; called by muse, mutect2, varscan2
- TRAF4 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99262041; called by muse, mutect2, varscan2
- TRAM1L1 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV60292059; called by muse, mutect2, varscan2
- TRIM42 | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99648500; called by muse, varscan2
- TTC33 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100531955; called by muse, mutect2, varscan2
- TTN | c.54305A>C p.K18102T (on ENST00000591111; = p.K10678T on NM_003319.4) | Missense Mutation (SNP) | VAF 222/410 reads (54%) | PolyPhen benign (0.037); catalogued as COSV100618983; called by muse, mutect2, varscan2
- UBLCP1 | c.585+2T>G p.X195_splice | Splice Site (SNP) | VAF 21/24 reads (88%) | catalogued as COSV99707390; called by muse, mutect2, varscan2
- UBTF | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100255996; called by muse, mutect2, varscan2
- UHRF1 | c.1517G>A p.R506K (on ENST00000612630 / NM_001290050.1; = p.R519K on NM_013282.4) | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.969); catalogued as COSV99503578; called by muse, mutect2, varscan2
- UNC13C | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV99519559; called by muse, mutect2, varscan2
- UNC5D | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.818); catalogued as COSV99776565; called by muse, mutect2, varscan2
- UNC5D | c.2313+2T>A p.X771_splice | Splice Site (SNP) | VAF 198/288 reads (69%) | catalogued as COSV99776568; called by muse, mutect2, varscan2
- UNC79 | c.1471G>A p.D491N (on ENST00000393151 / NM_001346218.2; = p.D314N on NM_020818.5) | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.52); catalogued as COSV56410865; called by muse, mutect2, varscan2
- VWC2L | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.331); catalogued as COSV100435846, COSV100436029; called by muse, mutect2, varscan2
- WDR33 | c.3107G>C p.G1036A | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV100460294; called by muse, mutect2, varscan2
- ZFHX4 | c.2782C>A p.R928S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766344610, COSV51494427, COSV99267636; called by muse, mutect2, varscan2
- ZFP64 | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99402696; called by muse, mutect2, varscan2
- ZGRF1 | c.4351A>G p.T1451A | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1307958835, COSV101500629; called by muse, mutect2, varscan2
- ZNF106 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55520242; called by muse, mutect2, varscan2
- ZNF236 | c.2960G>C p.R987P | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99470629; called by muse, mutect2, varscan2
- AFF2 | c.1013del p.P338Qfs*11 | Frame Shift Del (DEL) | VAF 37/53 reads (70%) | called by mutect2, pindel, varscan2
- BCAT1 | c.871del p.R291Gfs*26 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- DYNLL1 | c.176_177insT p.R60Efs*5 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel*, varscan2
- FRMPD1 | c.2561del p.L854Rfs*10 | Frame Shift Del (DEL) | VAF 42/58 reads (72%) | called by mutect2, pindel, varscan2
- GRIK1 | c.1911dup p.G638Rfs*51 | Frame Shift Ins (INS) | VAF 48/77 reads (62%) | called by mutect2, pindel, varscan2
- IGHG1 | c.201C>G p.S67R | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-12 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by mutect2, varscan2
- IGKV1D-43 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-43 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK9 | c.180del p.Q61Sfs*5 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- MAP2K7 | c.884_887dup p.K296Nfs*6 | Frame Shift Ins (INS) | VAF 38/58 reads (66%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.328dup p.Y110Lfs*8 | Frame Shift Ins (INS) | VAF 73/111 reads (66%) | called by mutect2, pindel, varscan2
- RPL30 | c.5_7del p.V2del | In Frame Del (DEL) | VAF 40/96 reads (42%) | called by pindel, varscan2
- SHANK3 | c.1523del p.G508Afs*16 | Frame Shift Del (DEL) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- TAF6L | c.1070_1071del p.K357Sfs*93 | Frame Shift Del (DEL) | VAF 70/174 reads (40%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.306del p.W102Cfs*8 | Frame Shift Del (DEL) | VAF 80/156 reads (51%) | called by mutect2, pindel, varscan2
- ACRV1 | c.423T>C p.D141= | Silent (SNP) | VAF 111/230 reads (48%) | catalogued as COSV100223582; called by muse, mutect2, varscan2
- ALMS1 | c.9369G>T p.L3123= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV100042885; called by muse, mutect2, varscan2
- ARRDC1 | c.700C>A p.R234= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100604026; called by muse, mutect2
- BMPER | c.795T>A p.T265= | Silent (SNP) | VAF 47/53 reads (89%) | catalogued as COSV99779928; called by muse, mutect2, varscan2
- CDH6 | c.1812G>T p.A604= | Silent (SNP) | VAF 96/148 reads (65%) | catalogued as COSV54079281, COSV99419697; called by muse, mutect2, varscan2
- CLEC4F | c.1179A>T p.L393= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV99713814; called by muse, mutect2, varscan2
- CNGA1 | c.1101G>A p.R367= | Silent (SNP) | VAF 108/270 reads (40%) | catalogued as COSV100652260; called by muse, mutect2, varscan2
- CYB561 | c.153C>T p.N51= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as COSV100669132; called by muse, mutect2, varscan2
- DMBT1 | c.96A>T p.S32= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as COSV100353366; called by muse, mutect2, varscan2
- DNHD1 | c.12654T>C p.S4218= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV99600395; called by muse, mutect2, varscan2
- DYSF | c.3861T>C p.I1287= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV99248261; called by muse, mutect2, varscan2
- EOLA2 | c.303C>G p.P101= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs368857106, COSV100778083; called by muse, mutect2, varscan2
- EYS | c.204T>G p.T68= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as COSV100676720, COSV60999762; called by muse, mutect2, varscan2
- FAT4 | c.12312T>A p.V4104= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV100629084; called by muse, mutect2, varscan2
- FBN1 | c.3456G>A p.A1152= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs777442762, COSV100353920; called by muse, mutect2
- FOXJ3 | c.135A>T p.T45= | Silent (SNP) | VAF 88/196 reads (45%) | catalogued as COSV100691977; called by muse, mutect2, varscan2
- FSHR | c.1221T>A p.A407= | Silent (SNP) | VAF 37/386 reads (10%) | catalogued as COSV100437469; called by muse, mutect2
- GADD45GIP1 | c.204C>T p.S68= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as rs1361264751, COSV100380272; called by muse, mutect2, varscan2
- IGKV1-12 | c.240C>A p.V80= | Silent (SNP) | VAF 24/176 reads (14%) | called by mutect2, varscan2
- IGSF9B | c.2727G>A p.K909= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV100317416; called by muse, mutect2
- INTS5 | c.2091A>G p.L697= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV100399698; called by muse, mutect2, varscan2
- KLF7 | c.129A>G p.L43= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as rs1316909713, COSV100519214; called by muse, mutect2, varscan2
- LRP3 | c.1158G>T p.L386= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53505633; called by muse, mutect2, varscan2
- LRRN3 | c.195C>A p.A65= | Silent (SNP) | VAF 55/241 reads (23%) | catalogued as COSV100071541; called by muse, mutect2, varscan2
- MAP1A | c.6807A>G p.S2269= | Silent (SNP) | VAF 80/142 reads (56%) | catalogued as COSV55807585; called by muse, mutect2, varscan2
- NCR1 | c.630C>A p.V210= | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as COSV99401025; called by muse, mutect2, varscan2
- NEDD9 | c.1662G>A p.E554= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV101060876; called by muse, mutect2, varscan2
- NOSTRIN | c.315A>G p.L105= (on ENST00000317647 / NM_001039724.4; = p.L27= on NM_052946.3) | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV100473763; called by muse, mutect2, varscan2
- NRK | c.1257G>T p.L419= | Silent (SNP) | VAF 32/34 reads (94%) | catalogued as COSV99688286; called by muse, mutect2, varscan2
- OR2L8 | c.447C>A p.I149= | Silent (SNP) | VAF 125/249 reads (50%) | catalogued as COSV100594246, COSV61725550; called by muse, mutect2, varscan2
- OR4D6 | c.723G>T p.T241= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100271754, COSV55660072; called by muse, mutect2, varscan2
- OR4S2 | c.897G>T p.L299= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as COSV100412707; called by muse, mutect2, varscan2
- PCLO | c.3126G>A p.K1042= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100434054; called by muse, mutect2, varscan2
- PLXNA4 | c.1752C>T p.V584= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV100325227; called by muse, mutect2, varscan2
- PRR23B | c.525C>T p.A175= | Silent (SNP) | VAF 5/117 reads (4%) | catalogued as rs1434707319, COSV61494114; called by muse, mutect2
- RSPH6A | c.1344G>A p.Q448= | Silent (SNP) | VAF 51/55 reads (93%) | catalogued as COSV99679904; called by muse, mutect2, varscan2
- SQLE | c.1143C>T p.D381= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99772178; called by muse, mutect2, varscan2
- TNFRSF8 | c.426G>T p.T142= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV99821624; called by mutect2, varscan2
- TTN | c.37215T>A p.I12405= (on ENST00000591111; = p.I4981= on NM_003319.4) | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as COSV100618984; called by muse, mutect2, varscan2
- ZFAT | c.420G>A p.L140= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV100914751; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1992C>T p.I664= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs774938976, COSV60157394; called by muse, mutect2, varscan2
- KIR3DX1 | n.888G>T | RNA (SNP) | VAF 56/64 reads (88%) | catalogued as COSV99683454; called by muse, mutect2, varscan2
- SNORD115-43 | n.63A>G | RNA (SNP) | VAF 43/471 reads (9%) | catalogued as rs1012700702; called by muse, mutect2
- ZNF135 | c.-44A>C | 5'UTR (SNP) | VAF 18/21 reads (86%) | catalogued as COSV99991785; called by muse, mutect2, varscan2
